Somatic mutation profile of tumor specimen MMRF_2464_1_BM_CD138pos (aliquot MMRF_2464_1_BM_CD138pos_T1_KHS5U_L11627) from MMRF case MMRF_2464, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,041 days).
Specimen MMRF_2464_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7657925-ed3f-4bd4-9dd7-10f0891741a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2464_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2464_1_PB_Whole_C3_KHS5U_L11628; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cf48492-34c6-45e1-a4ea-3739bfead041

The open-access MAF lists 117 somatic variants for this specimen: 45 protein-altering or splice-affecting, 17 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 32, Silent 17, Intron 12, 5'UTR 5, RNA 2, 3'Flank 2, 5'Flank 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF40 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs147702351; called by muse, mutect2, varscan2
- ATP10D | c.1916C>T p.S639F | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV56712236, COSV99905883; called by muse, mutect2, varscan2
- AXL | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 101/174 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1306116384, COSV56568438; called by muse, mutect2, varscan2
- CHST5 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318636117, COSV60338347; called by muse, mutect2, varscan2
- CLUAP1 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1327474475, COSV57093899; called by muse, mutect2
- COL27A1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs145824150, COSV61924970; called by muse, mutect2, varscan2
- EEF1A1 | c.290A>T p.D97V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100303492; called by muse, mutect2, varscan2
- ESYT1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748140521, COSV99919986; called by muse, mutect2, varscan2
- FBN3 | c.6538C>T p.R2180C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138756263, COSV54456109; called by muse, mutect2, varscan2
- HAO1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576373242, COSV66493343; called by muse, mutect2, varscan2
- IGHG2 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229664156; called by muse, mutect2, varscan2
- IGHV1-69 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376711593; called by mutect2, varscan2
- IGHV2-70 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs377238058; called by muse, varscan2
- IMPG1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs760658197; called by muse, mutect2, varscan2
- NEDD8 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 118/191 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV51659637; called by muse, mutect2, varscan2
- NUFIP2 | c.140A>G p.H47R | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.075); catalogued as rs996980603; called by muse, mutect2, varscan2
- NWD1 | c.3742G>C p.E1248Q | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.469); catalogued as COSV60348534; called by muse, mutect2, varscan2
- OBSCN | c.13277C>T p.T4426M | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1351744113; called by muse, mutect2, varscan2
- OR4K5 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 14/496 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV60003307; called by muse, mutect2
- PBX3 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as rs376106319; called by muse, mutect2, varscan2
- PCDH10 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1166023689; called by muse, mutect2
- PCDHA13 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1554174625, COSV56505136; called by muse, mutect2, varscan2
- SCN8A | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 119/237 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61976013; called by muse, mutect2, varscan2
- TXNRD1 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1419647714; called by muse, mutect2
- UNC5A | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 171/247 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56171642; called by muse, mutect2, varscan2
- AC113208.3 | n.2411+1G>A | Splice Site (SNP) | VAF 104/190 reads (55%) | called by muse, mutect2, varscan2
- BCL2L14 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BRWD1 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP120 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- DCC | c.647A>T p.N216I | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2
- FOCAD | c.3865G>T p.D1289Y | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- IGHV1-69D | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- IGHV1-69D | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 114/218 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.166); called by muse, varscan2
- KDM6B | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
- LRP1B | c.8381T>G p.L2794R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MKI67 | c.6107G>T p.G2036V | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYOZ2 | c.41A>G p.Q14R | Missense Mutation (SNP) | VAF 87/305 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PCDHB3 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POSTN | c.2476T>C p.S826P | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PROX1 | c.448A>C p.S150R | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SON | c.2242T>G p.S748A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TENT5C | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TTC13 | c.1695G>T p.M565I | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- VSTM2A | c.299C>G p.T100R | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN2 | c.2466G>A p.T822= | Silent (SNP) | VAF 87/169 reads (51%) | catalogued as rs746365850, COSV63975806; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM7 | c.9C>T p.P3= | Silent (SNP) | VAF 43/54 reads (80%) | catalogued as rs1178281383, COSV51543940; called by muse, mutect2, varscan2
- ATXN1 | c.948G>A p.Q316= | Silent (SNP) | VAF 62/157 reads (39%) | called by muse, mutect2, varscan2
- CDH17 | c.300C>T p.D100= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs747266533, COSV50345797; called by muse, mutect2, varscan2
- ERBB4 | c.1149C>A p.A383= | Silent (SNP) | VAF 7/161 reads (4%) | called by muse, mutect2
- FSCB | c.564A>C p.G188= | Silent (SNP) | VAF 103/179 reads (58%) | called by muse, mutect2, varscan2
- GAS6 | c.1236G>A p.P412= | Silent (SNP) | VAF 99/203 reads (49%) | catalogued as rs139784202; called by muse, mutect2, varscan2
- IGLL5 | c.141C>T p.S47= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as rs191888936, COSV73248969, COSV73251302; called by muse, mutect2, varscan2
- IGLV3-25 | c.66G>A p.E22= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as rs376421895; called by muse, mutect2, varscan2
- LAMA2 | c.7479C>T p.S2493= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as rs368989339; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- OPN4 | c.981G>T p.L327= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- PEAR1 | c.2733G>A p.E911= | Silent (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- PIK3C2A | c.2506C>T p.L836= | Silent (SNP) | VAF 86/129 reads (67%) | catalogued as rs778644549; called by muse, mutect2, varscan2
- RPL36A | c.247C>T p.L83= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1372882392, COSV99516296; called by muse, mutect2
- SIGLEC11 | c.177C>T p.P59= | Silent (SNP) | VAF 66/224 reads (29%) | called by muse, mutect2, varscan2
- ZNF516 | c.1599C>T p.H533= | Silent (SNP) | VAF 89/168 reads (53%) | catalogued as rs1265151662; called by muse, mutect2, varscan2
- ZNF699 | c.57A>C p.V19= | Silent (SNP) | VAF 82/264 reads (31%) | called by muse, mutect2, varscan2
- AAK1 | c.1777-21T>C | Intron (SNP) | VAF 38/82 reads (46%) | called by muse, varscan2
- AC011410.1 | n.156G>A | RNA (SNP) | VAF 40/252 reads (16%) | catalogued as rs544519245; called by muse, mutect2, varscan2
- CBX4 | c.-135C>G | 5'UTR (SNP) | VAF 9/16 reads (56%) | catalogued as rs933358929; called by muse, varscan2
- CDC40 | c.*221T>C | 3'UTR (SNP) | VAF 106/257 reads (41%) | called by muse, mutect2, varscan2
- CDH11 | c.*3239A>C | 3'UTR (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2
- CXCL5 | c.109+16G>A | Intron (SNP) | VAF 10/195 reads (5%) | called by muse, mutect2
- EDEM3 | c.*2242T>G | 3'UTR (SNP) | VAF 26/36 reads (72%) | called by muse, mutect2, varscan2
- F2R | c.*656_*657del | 3'UTR (DEL) | VAF 34/118 reads (29%) | called by pindel, varscan2
- FAM169A | c.*524_*525del | 3'UTR (DEL) | VAF 41/159 reads (26%) | called by mutect2, pindel, varscan2
- FBN2 | c.-235G>A | 5'UTR (SNP) | VAF 25/83 reads (30%) | catalogued as rs1487107361; called by muse, mutect2, varscan2
- FBXL2 | c.*1008G>C | 3'UTR (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- FER | c.*6857A>G | 3'UTR (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- GDF7 | c.*241T>C | 3'UTR (SNP) | VAF 41/127 reads (32%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.-389C>A | 5'UTR (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- HSP90B1 | c.1374+54G>A | Intron (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- IGLC3 | c.*21A>G | 3'UTR (SNP) | VAF 46/58 reads (79%) | catalogued as rs200606818; called by muse, mutect2, varscan2
- IL17RD | c.*1289T>A | 3'UTR (SNP) | VAF 44/188 reads (23%) | called by muse, mutect2, varscan2
- INPP4A | c.-94C>T | 5'UTR (SNP) | VAF 119/246 reads (48%) | called by muse, mutect2, varscan2
- JOSD1 | c.*1149T>G | 3'UTR (SNP) | VAF 4/101 reads (4%) | called by muse, mutect2
- KCNIP4 | c.62-101135C>T | Intron (SNP) | VAF 9/215 reads (4%) | called by muse, mutect2
- KLF7 | c.*665G>A | 3'UTR (SNP) | VAF 7/133 reads (5%) | catalogued as rs1465122510; called by muse, mutect2
- LINC02291 | n.814T>G | RNA (SNP) | VAF 29/41 reads (71%) | called by muse, mutect2, varscan2
- MBTPS2 | c.970+2388G>C | Intron (SNP) | VAF 10/10 reads (100%) | called by muse, varscan2
- MBTPS2 | c.970+2392C>T | Intron (SNP) | VAF 10/10 reads (100%) | called by muse, varscan2
- MCM8 | c.1255-438G>A | Intron (SNP) | VAF 19/30 reads (63%) | catalogued as rs1262470366; called by muse, mutect2
- MKX | c.*273A>C | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2
- NALCN | c.*59G>C | 3'UTR (SNP) | VAF 10/290 reads (3%) | called by muse, mutect2
- NFKBID | c.*49G>A | 3'UTR (SNP) | VAF 13/67 reads (19%) | catalogued as rs774877906; called by muse, mutect2, varscan2
- PAX7 | c.*328G>T | 3'UTR (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- PCDH7 | c.*4C>T | 3'UTR (SNP) | VAF 87/299 reads (29%) | catalogued as rs777852903; called by muse, mutect2, varscan2
- PCYOX1L | c.*658A>G | 3'UTR (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- PGA3 | c.*191C>A | 3'UTR (SNP) | VAF 7/49 reads (14%) | called by mutect2, varscan2
- PKN2 | c.*550_*551del | 3'UTR (DEL) | VAF 23/59 reads (39%) | catalogued as rs935576354; called by mutect2, pindel, varscan2
- POGLUT3 | c.*1197A>T | 3'UTR (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- PTCH1 | c.*127C>A | 3'UTR (SNP) | VAF 46/345 reads (13%) | called by muse, mutect2, varscan2
- PTPN3 | c.*2782T>A | 3'UTR (SNP) | VAF 46/115 reads (40%) | called by muse, mutect2, varscan2
- PTPN6 | chr12:6951262 C>T | 5'Flank (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- RNU6-1224P | chr8:102529357 C>T | 3'Flank (SNP) | VAF 56/128 reads (44%) | called by muse, mutect2, varscan2
- SGK1 | c.787-109A>C | Intron (SNP) | VAF 22/49 reads (45%) | catalogued as rs1189291916; called by muse, mutect2, varscan2
- SGK1 | c.152+29C>T | Intron (SNP) | VAF 28/56 reads (50%) | catalogued as rs375352335; called by mutect2, varscan2
- SIK2 | c.*2214C>A | 3'UTR (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- SLIRP | chr14:77708079 G>A | 5'Flank (SNP) | VAF 12/79 reads (15%) | called by mutect2, varscan2
- SLITRK4 | chrX:143628014 T>G | 3'Flank (SNP) | VAF 13/15 reads (87%) | called by muse, mutect2, varscan2
- STK10 | c.*2606G>A | 3'UTR (SNP) | VAF 102/294 reads (35%) | catalogued as rs771082925; called by muse, mutect2, varscan2
- TBC1D14 | c.*495T>A | 3'UTR (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- THAP5 | c.-50C>T | 5'UTR (SNP) | VAF 85/134 reads (63%) | catalogued as rs1448010532; called by muse, mutect2, varscan2
- TMEM127 | c.*1232A>C | 3'UTR (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2, varscan2
- TMPRSS2 | c.15+133A>T | Intron (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2
- TP53I11 | c.*530A>C | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- TP53I11 | c.*529G>T | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- TSPYL5 | c.*1624C>T | 3'UTR (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- USP46 | c.36+2679C>A | Intron (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- VAPA | c.*3632T>G | 3'UTR (SNP) | VAF 52/66 reads (79%) | called by muse, mutect2, varscan2
- ZADH2 | c.*2019G>A | 3'UTR (SNP) | VAF 30/63 reads (48%) | catalogued as rs1301800349; called by muse, mutect2, varscan2
- ZNF793 | c.238+69T>A | Intron (SNP) | VAF 21/115 reads (18%) | catalogued as rs1045335696; called by muse, mutect2, varscan2
